CPTAC case C3N-01011 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ed69df53-631b-4c3a-af08-e502cc64129a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1939; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 77.5 years (28,289 days); Year of diagnosis: 2016; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,068 days (2.9 years); Progression or recurrence: yes; Days to recurrence: 623 days (1.7 years); Days to last follow up: 1,068 days (2.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm (a second GDC size field records 4.5 cm); Lymph node involvement: Positive; Lymph nodes positive: 7; Lymph nodes tested: 31; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 444 days (1.2 years); Disease response: Complete Response.
- Days to follow up: 765 days (2.1 years); Disease response: With Tumor.
- Days to follow up: 1,068 days (2.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 623 days (1.7 years).

Other clinical attributes
- Weight: 68 kg; Height: 157.5 cm; BMI: 27.41.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 3; Cigarettes per day: 3; Tobacco smoking onset year: 1996; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 26.

Biospecimens (7 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01011-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 164 mg.
- Sample C3N-01011-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 31 days; Initial weight: 271 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01011-22: Section location: Head; Percent tumor nuclei: 10; Percent necrosis: 1.
- Sample C3N-01011-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 62 mg.
- Sample C3N-01011-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 31 days; Initial weight: 328 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01011-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 260 mg.
- Sample C3N-01011-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 31 days; Method of sample procurement: Blood Draw.
- Sample C3N-01011-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
